Somatic mutation profile of tumor specimen TCGA-DX-A48P-01A (aliquot TCGA-DX-A48P-01A-11D-A307-09) from TCGA case TCGA-DX-A48P, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 54.2 years (19,794 days).
Specimen TCGA-DX-A48P-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 64940247-7219-4488-b9a9-8390b7964308.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A48P-10A (Blood Derived Normal), aliquot TCGA-DX-A48P-10A-01D-A307-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7616de77-735e-42ee-8922-a06501489b11

The open-access MAF lists 43 somatic variants for this specimen: 30 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 12, In Frame Del 2, Intron 1, Frame Shift Del 1, Frame Shift Ins 1, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRG6 | c.1244C>A p.S415Y | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.51); catalogued as COSV99745970, COSV99748607; called by muse, mutect2, varscan2
- AHNAK | c.3793C>T p.P1265S | Missense Mutation (SNP) | VAF 44/337 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.79); catalogued as COSV99946088; called by muse, mutect2, varscan2
- BAG4 | c.934C>A p.H312N | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV99782044; called by muse, mutect2, varscan2
- BPI | c.1376C>T p.P459L (on ENST00000262865; = p.P455L on NM_001725.3) | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368496977, COSV53403586, COSV99481034; called by muse, mutect2
- C2CD5 | c.127T>A p.Y43N | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.334); catalogued as COSV100449012; called by muse, mutect2
- CA12 | c.1060G>C p.A354P | Missense Mutation (SNP) | VAF 81/159 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as COSV51607218, COSV99458724; called by muse, mutect2, varscan2
- COL4A4 | c.221G>A p.G74D | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1320190484, COSV100307670; called by muse, mutect2
- DLGAP1 | c.1141C>G p.Q381E | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.9); catalogued as COSV59831117; called by muse, mutect2, varscan2
- DNAJC5B | c.545A>G p.N182S | Missense Mutation (SNP) | VAF 115/258 reads (45%) | SIFT tolerated (0.6); PolyPhen benign (0.018); catalogued as COSV99395922; called by muse, mutect2, varscan2
- GPC6 | c.328C>T p.R110* | Nonsense Mutation (SNP) | VAF 26/184 reads (14%) | catalogued as rs772667427, COSV100989478, COSV100989970; called by muse, mutect2, varscan2
- HSD17B1 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 24/207 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.303); catalogued as COSV99864925; called by muse, mutect2, varscan2
- IFT122 | c.2819G>T p.G940V (on ENST00000348417 / NM_052989.3; = p.G881V on NM_018262.4) | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV99959816; called by muse, mutect2, varscan2
- IMPG1 | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as COSV100886650; called by muse, mutect2, varscan2
- LRRIQ3 | c.983A>G p.H328R | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as COSV100599436; called by muse, mutect2, varscan2
- NCLN | c.1390C>G p.R464G | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as COSV99859601, COSV99860108; called by muse, mutect2, varscan2
- PLOD2 | c.1973A>T p.E658V | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as COSV99283287; called by muse, mutect2, varscan2
- PRDM9 | c.935G>T p.W312L | Missense Mutation (SNP) | VAF 91/192 reads (47%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV99689897, COSV99691218; called by muse, mutect2, varscan2
- SCN9A | c.1309G>C p.A437P | Missense Mutation (SNP) | VAF 67/164 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.864); catalogued as COSV100314147; called by muse, mutect2, varscan2
- SDK1 | c.4004C>T p.T1335M | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs140791078, COSV101268661; called by muse, mutect2, varscan2
- SLC22A8 | c.1216+1G>T p.X406_splice | Splice Site (SNP) | VAF 6/32 reads (19%) | catalogued as rs773430800, COSV100268076; called by muse, mutect2
- SMOC1 | c.1165C>T p.R389C | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756866673, COSV100734803; called by muse, mutect2, varscan2
- TBC1D1 | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 59/132 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs749274148, COSV54726897; called by muse, mutect2, varscan2
- TLR3 | c.28T>A p.F10I | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.035); catalogued as COSV99711206; called by muse, mutect2
- TRIM45 | c.127C>T p.P43S | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99868722; called by muse, mutect2, varscan2
- USH2A | c.6631G>A p.G2211S | Missense Mutation (SNP) | VAF 58/147 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100236183, COSV100242252; called by muse, mutect2, varscan2
- ZNF236 | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as rs373923548; called by muse, mutect2, varscan2
- FST | c.918del p.L307Yfs*4 | Frame Shift Del (DEL) | VAF 37/101 reads (37%) | called by mutect2, pindel, varscan2
- SURF6 | c.776_796del p.G259_E265del | In Frame Del (DEL) | VAF 14/50 reads (28%) | called by mutect2, varscan2
- TSPYL2 | c.1524_1544del p.S510_E516del | In Frame Del (DEL) | VAF 30/89 reads (34%) | called by mutect2, varscan2
- WASHC5 | c.2608dup p.T870Nfs*59 | Frame Shift Ins (INS) | VAF 27/149 reads (18%) | called by mutect2, pindel, varscan2
- ADGRG4 | c.6102A>G p.T2034= | Silent (SNP) | VAF 13/102 reads (13%) | catalogued as COSV54949363; called by muse, mutect2, varscan2
- ALPK2 | c.6033C>A p.I2011= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV100864787; called by muse, mutect2
- CFAP77 | c.375C>T p.I125= | Silent (SNP) | VAF 10/104 reads (10%) | catalogued as COSV100546121; called by muse, mutect2
- FAT3 | c.5694T>G p.V1898= | Silent (SNP) | VAF 29/75 reads (39%) | catalogued as COSV99970741; called by muse, mutect2, varscan2
- LHFPL4 | c.462C>T p.T154= | Silent (SNP) | VAF 52/114 reads (46%) | catalogued as COSV99805689; called by muse, mutect2, varscan2
- NSMAF | c.2388C>T p.T796= | Silent (SNP) | VAF 83/219 reads (38%) | catalogued as rs1373324020, COSV50687432, COSV99233431; called by muse, mutect2, varscan2
- PCDHGA2 | c.1872C>T p.G624= | Silent (SNP) | VAF 43/323 reads (13%) | catalogued as rs890883912, COSV99531201; called by muse, mutect2, varscan2
- PIGQ | c.156G>A p.V52= | Silent (SNP) | VAF 33/58 reads (57%) | catalogued as rs1242906892, COSV99216526; called by muse, mutect2, varscan2
- POU6F2 | c.441C>A p.T147= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as rs751554807, COSV68873195, COSV68874385; called by muse, mutect2, varscan2
- TEX45 | c.1344A>G p.S448= | Silent (SNP) | VAF 40/105 reads (38%) | catalogued as COSV100861827; called by muse, mutect2, varscan2
- TSPAN32 | c.441G>A p.A147= | Silent (SNP) | VAF 14/121 reads (12%) | catalogued as rs764063848, COSV99478197; called by muse, mutect2, varscan2
- ZNF251 | c.2016_*29delinsGTG | Silent (DEL) | VAF 37/80 reads (46%) | called by pindel, varscan2*
- PMF1 | c.162-6743_162-6715del | Intron (DEL) | VAF 80/229 reads (35%) | called by mutect2, pindel, varscan2
